MMRF case MMRF_2281 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/98eb3354-e412-4996-9274-04cda4827dc1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.8 years (18,936 days); ISS stage: I; Days to last known disease status: 821 days (2.2 years); Days to last follow up: 821 days (2.2 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 4.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 63.6 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 11 g/dL; Glucose 4.73 mmol/L; C-Reactive Protein 0.156 mg/dL.
- Day 86: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Immunoglobulin G 9.91 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 4.4 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 13 ×10⁹/L; Absolute Neutrophil 12.4 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 6 mmol/L.
- Day 177 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 4.49 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 5.72 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5.07 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 261 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 3.42 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 5 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 4.99 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 6.66 mmol/L.
- Day 372 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.46 mmol/L.
- Day 456 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.
- Day 541 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.06 mmol/L.
- Day 626: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.07 mmol/L.
- Day 737 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 4.35 mmol/L.
- Day 821 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 42 g/L; Total Protein 8.1 g/dL; Glucose 4.68 mmol/L.

Other clinical attributes
- Day -17: Weight: 92 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2281_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_2281_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
